Somatic mutation profile of tumor specimen MMRF_2605_1_BM_CD138pos (aliquot MMRF_2605_1_BM_CD138pos_T1_KHS5U_L12887) from MMRF case MMRF_2605, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,744 days).
Specimen MMRF_2605_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 775a6e15-e219-43f9-abeb-09bd06e06c3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2605_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2605_1_PB_Whole_C3_KHS5U_L12888; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/588b26b1-571d-4480-9e45-55113ace3a58

The open-access MAF lists 92 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 23, Intron 18, Silent 7, 5'UTR 5, Nonsense Mutation 3, 3'Flank 3, Splice Region 2, RNA 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC8 | c.822+7G>C | Splice Region (SNP) | VAF 48/84 reads (57%) | catalogued as rs765890511, COSV56851228; called by muse, mutect2, varscan2
- ALS2 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs752311938; called by muse, mutect2, varscan2
- CAMKK1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs571797127; called by muse, mutect2, varscan2
- CEP120 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV60264352; called by muse, mutect2, varscan2
- COL4A3 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780977535; called by muse, mutect2, varscan2
- DST | c.22103G>C p.R7368T (on ENST00000361203 / NM_001374722.1; = p.R5078T on NM_015548.5) | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV55011551; called by muse, mutect2, varscan2
- IGHV2-70 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 102/207 reads (49%) | catalogued as rs61733526; called by muse, varscan2
- IGHV2-70 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs549292393; called by muse, varscan2
- IGHV6-1 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs72715485; called by muse, varscan2
- IGHV6-1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs1555405764; called by muse, varscan2
- LTB | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.341); catalogued as rs1366683874; called by muse, mutect2, varscan2
- MME | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs199804325, COSV64707147; called by muse, mutect2, varscan2
- MYO10 | c.4798C>T p.R1600* | Nonsense Mutation (SNP) | VAF 70/149 reads (47%) | catalogued as rs779142199, COSV57030257; called by muse, mutect2, varscan2
- PIKFYVE | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 81/233 reads (35%) | catalogued as rs1195336213, COSV52241660; called by muse, mutect2, varscan2
- TMIGD3 | c.707G>A p.R236K (on ENST00000369717 / NM_001081976.2; = p.R317K on NM_020683.7) | Missense Mutation (SNP) | VAF 132/152 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100778429; called by muse, mutect2, varscan2
- ZFP69B | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs1416295121, COSV64315544; called by muse, mutect2
- ACTL6B | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 134/539 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ALS2CL | c.2682C>T p.A894= | Splice Region (SNP) | VAF 118/228 reads (52%) | called by muse, mutect2, varscan2
- DLX2 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- FLG | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HDAC11 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- IGLV4-69 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- LSG1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- LTBP3 | c.1423dup p.E475Gfs*3 | Frame Shift Ins (INS) | VAF 142/372 reads (38%) | called by mutect2, pindel, varscan2
- MLF2 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NDUFV1 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 102/525 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMS1 | c.2438T>G p.L813R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM6 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RALGPS1 | c.160T>C p.F54L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SFMBT1 | c.2409del p.F804Sfs*10 | Frame Shift Del (DEL) | VAF 123/327 reads (38%) | called by mutect2, pindel, varscan2
- SHFL | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC26A9 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TMEM179 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 156/294 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AXIN2 | c.1659G>A p.S553= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs967153637, COSV61058901; called by muse, mutect2, varscan2
- IGHV3-23 | c.189G>A p.G63= | Silent (SNP) | VAF 254/728 reads (35%) | catalogued as rs147202943; called by muse, varscan2
- IGHV6-1 | c.162T>A p.A54= | Silent (SNP) | VAF 28/30 reads (93%) | called by muse, varscan2
- PPARG | c.661C>T p.L221= (on ENST00000287820 / NM_015869.5; = p.L191= on NM_005037.7) | Silent (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- RANBP2 | c.8157A>T p.T2719= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- SLC7A5 | c.1336C>T p.L446= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- TSKU | c.375C>T p.A125= | Silent (SNP) | VAF 130/528 reads (25%) | catalogued as rs147461076; called by muse, mutect2, varscan2
- AC140125.2 | n.1171T>A | RNA (SNP) | VAF 240/516 reads (47%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.49-88_49-68del | Intron (DEL) | VAF 65/160 reads (41%) | called by mutect2, pindel, varscan2
- ANTXR1 | c.*9G>T | 3'UTR (SNP) | VAF 110/230 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.*156T>A | 3'UTR (SNP) | VAF 14/145 reads (10%) | catalogued as rs979591113, COSV99393216; called by muse, varscan2
- C10orf67 | c.*391G>T | 3'UTR (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CARD8 | c.351-360T>A | Intron (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- CCDC85C | c.867+980A>C | Intron (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- CCN2 | c.*115T>G | 3'UTR (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2, varscan2
- CD36 | c.1255-78A>T | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- CLLU1 | n.482G>T | RNA (SNP) | VAF 53/141 reads (38%) | catalogued as rs1330390299; called by muse, mutect2, varscan2
- CMSS1 | c.580-124C>T | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- CRB2 | c.*1551A>G | 3'UTR (SNP) | VAF 81/204 reads (40%) | called by muse, mutect2, varscan2
- CRISPLD2 | c.240+98C>T | Intron (SNP) | VAF 24/24 reads (100%) | catalogued as rs1484781674; called by muse, mutect2, varscan2
- CSRNP3 | c.*7219G>A | 3'UTR (SNP) | VAF 83/214 reads (39%) | called by muse, mutect2, varscan2
- CYP4V2 | c.*219G>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- DOCK5 | c.-214G>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- EGFR | c.*4309C>A | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- EN2 | c.-227G>A | 5'UTR (SNP) | VAF 24/399 reads (6%) | catalogued as rs1460125142; called by muse, mutect2
- FEZF2 | c.-58-9G>A | Intron (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- GABRA1 | c.-15-98C>A | Intron (SNP) | VAF 153/346 reads (44%) | called by muse, mutect2, varscan2
- GABRA1 | c.560-68A>T | Intron (SNP) | VAF 14/56 reads (25%) | called by muse, varscan2
- HLCS | c.*2849G>A | 3'UTR (SNP) | VAF 120/254 reads (47%) | called by muse, mutect2, varscan2
- IGFBP5 | c.-576del | 5'UTR (DEL) | VAF 27/74 reads (36%) | catalogued as rs971398760; called by mutect2, pindel, varscan2
- IL2RB | c.*2020G>A | 3'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- LTB | c.162+138T>A | Intron (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
- MDM4 | c.*7999C>T | 3'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as rs545983711; called by muse, mutect2, varscan2
- MYO10 | c.*1351T>A | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- NAGK | c.-28C>T | 5'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- NBEAL1 | c.*1549G>T | 3'UTR (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- NKTR | c.1017+14G>C | Intron (SNP) | VAF 6/114 reads (5%) | catalogued as COSV51772722; called by muse, mutect2
- NRP2 | c.-125G>T | 5'UTR (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- OPCML | c.*2120C>A | 3'UTR (SNP) | VAF 73/132 reads (55%) | called by muse, mutect2, varscan2
- OXGR1 | c.*859T>C | 3'UTR (SNP) | VAF 86/90 reads (96%) | called by muse, mutect2, varscan2
- PATJ | c.4655+174T>C | Intron (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156885 C>G | 3'Flank (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- PCYT1A | c.708+45C>T | Intron (SNP) | VAF 104/230 reads (45%) | called by muse, mutect2, varscan2
- PGAP1 | c.148-1966A>G | Intron (SNP) | VAF 81/359 reads (23%) | called by muse, mutect2, varscan2
- PLCB2 | chr15:40284493 C>T | 3'Flank (SNP) | VAF 26/418 reads (6%) | catalogued as rs1409294823; called by muse, mutect2
- RASL11B | c.*280C>T | 3'UTR (SNP) | VAF 31/67 reads (46%) | catalogued as rs910439248; called by muse, mutect2, varscan2
- RPS6KA2 | c.*41C>T | 3'UTR (SNP) | VAF 38/83 reads (46%) | catalogued as rs775255143; called by muse, mutect2, varscan2
- SERPINB6 | c.48-927G>A | Intron (SNP) | VAF 128/297 reads (43%) | called by muse, mutect2, varscan2
- SETD4 | c.-37+254C>G | Intron (SNP) | VAF 62/159 reads (39%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.*350C>T | 3'UTR (SNP) | VAF 65/173 reads (38%) | catalogued as rs908868871; called by muse, mutect2, varscan2
- SLITRK4 | chrX:143626739 G>A | 3'Flank (SNP) | VAF 89/94 reads (95%) | called by muse, mutect2, varscan2
- SPRY3 | c.*4310A>G | 3'UTR (SNP) | VAF 122/289 reads (42%) | catalogued as rs1389755802; called by muse, mutect2, varscan2
- TCERG1 | c.*628G>A | 3'UTR (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- TEF | c.*420G>A | 3'UTR (SNP) | VAF 72/404 reads (18%) | called by muse, mutect2, varscan2
- TMTC1 | c.*3720G>A | 3'UTR (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- TRIM63 | c.*525A>G | 3'UTR (SNP) | VAF 58/63 reads (92%) | called by muse, mutect2, varscan2
- USP38 | c.2967+295dup | Intron (INS) | VAF 49/139 reads (35%) | called by mutect2, pindel, varscan2
- ZNF692 | c.180-63A>C | Intron (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
